Somatic mutation profile of tumor specimen TCGA-5U-AB0F-01A (aliquot TCGA-5U-AB0F-01A-11D-A423-09) from TCGA case TCGA-5U-AB0F, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 58.9 years (21,511 days).
Specimen TCGA-5U-AB0F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193587c6-8ff7-4ee1-b304-c1e0166aa492.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5U-AB0F-10A (Blood Derived Normal), aliquot TCGA-5U-AB0F-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/508494cb-5267-4ad8-bee5-bbb1bdd74a36

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'UTR 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 38/492 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- DIAPH3 | c.2287G>A p.D763N (on ENST00000400324 / NM_001042517.2; = p.D500N on NM_030932.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1327735988; called by muse, mutect2, varscan2
- PTPRA | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53789222; called by muse, mutect2, varscan2
- BRWD1 | c.4406T>G p.I1469S | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.018); called by muse, mutect2
- CFAP54 | c.5942G>A p.S1981N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- CLDND2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CXorf58 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- OR8B12 | c.419_420del p.C140Ffs*30 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- PTPRM | c.297T>G p.F99L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- MTAP | c.729C>T p.N243= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs778306013; called by muse, mutect2, varscan2
- SEZ6L | c.1128C>T p.D376= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs371203903; called by mutect2, varscan2
- NCAM1 | c.-166C>T | 5'UTR (SNP) | VAF 13/152 reads (9%) | catalogued as rs782148552; called by muse, mutect2
- NXF5 | n.1324G>A | RNA (SNP) | VAF 12/114 reads (11%) | catalogued as rs367948078; called by muse, mutect2
